Somatic mutation profile of tumor specimen C3L-00603-02 (aliquot CPT0064040006) from CPTAC case C3L-00603, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 72.3 years (26,424 days).
Specimen C3L-00603-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa5ce82f-5056-4931-9580-c0abe5cf392d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00603-31 (Blood Derived Normal), aliquot CPT0065370002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c834f5b2-da81-4ad3-8696-37e4662425f2

The open-access MAF lists 233 somatic variants for this specimen: 167 protein-altering or splice-affecting, 41 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 132, Silent 41, Nonsense Mutation 14, Intron 13, Frame Shift Del 9, RNA 6, Splice Site 5, Splice Region 4, 3'UTR 3, Frame Shift Ins 3, 5'Flank 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 153/315 reads (49%) | catalogued as rs879253911, CM941328, COSV52694461, COSV52816009, COSV53014483, COSV53470757; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRE1 | c.4C>T p.R2C | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.348); catalogued as rs775570503; called by muse, mutect2, varscan2
- ATAD2B | c.3305G>A p.R1102Q | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as rs1365341446; called by muse, mutect2, varscan2
- CAMK2G | c.159G>T p.R53= | Splice Region (SNP) | VAF 79/210 reads (38%) | catalogued as rs768334629; called by muse, mutect2
- CLPTM1 | c.1708G>T p.G570C | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs548487634, COSV61610846; called by muse, mutect2, varscan2
- COL11A2 | c.4690C>T p.Q1564* (on ENST00000341947 / NM_080680.3; = p.Q1457* on NM_080679.2) | Nonsense Mutation (SNP) | VAF 259/944 reads (27%) | catalogued as COSV100554529; called by muse, mutect2, varscan2
- CRB1 | c.265C>A p.P89T | Missense Mutation (SNP) | VAF 83/246 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.419); catalogued as COSV100959057; called by muse, mutect2, varscan2
- DEFB127 | c.205C>A p.P69T | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.076); catalogued as COSV66688623; called by muse, mutect2, varscan2
- DLGAP1 | c.1469G>A p.R490Q | Missense Mutation (SNP) | VAF 23/428 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1209043544; called by muse, mutect2
- DNAH8 | c.13352C>A p.P4451H | Missense Mutation (SNP) | VAF 153/455 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59437441, COSV59463040; called by muse, mutect2, varscan2
- DOCK5 | c.3289C>T p.H1097Y | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV52409172; called by muse, varscan2
- DPYD | c.1424G>T p.W475L | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.375); catalogued as rs1240771648, COSV64591091; called by muse, mutect2, varscan2
- FAT1 | c.6193G>A p.V2065I | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.096); catalogued as rs1165941519, COSV71676209; called by muse, mutect2
- FAT4 | c.13462G>T p.G4488W | Missense Mutation (SNP) | VAF 91/263 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV58698596; called by muse, mutect2, varscan2
- FEZF2 | c.1057del p.R353Afs*29 | Frame Shift Del (DEL) | VAF 90/230 reads (39%) | catalogued as COSV51863895; called by mutect2, pindel, varscan2
- HCN1 | c.1777C>G p.R593G | Missense Mutation (SNP) | VAF 73/285 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as rs989268235, COSV57491564; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HCN1 | c.933G>T p.W311C | Missense Mutation (SNP) | VAF 19/243 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57520543; called by muse, mutect2
- HERC2 | c.1762A>T p.S588C | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV55337201; called by muse, mutect2, varscan2
- HNF4A | c.1251G>T p.M417I | Missense Mutation (SNP) | VAF 192/593 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV57381863; called by muse, mutect2, varscan2
- IFI16 | c.1774G>C p.E592Q (on ENST00000295809 / NM_001364867.2; = p.E536Q on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as COSV99858166; called by muse, mutect2, varscan2
- KCNS1 | c.152C>A p.A51E | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV60260233; called by muse, mutect2, varscan2
- KNDC1 | c.487G>T p.G163W | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV100464757; called by muse, mutect2, varscan2
- LDHC | c.73A>T p.I25F | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV99772726; called by muse, mutect2, varscan2
- LIFR | c.705G>T p.W235C | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54693915; called by muse, mutect2, varscan2
- MAPKAPK3 | c.260A>T p.H87L | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs748745169; called by muse, mutect2, varscan2
- MC5R | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs781640318, COSV61254157; called by muse, mutect2, varscan2
- MCM10 | c.545C>T p.A182V (on ENST00000484800 / NM_182751.3; = p.A181V on NM_018518.5) | Missense Mutation (SNP) | VAF 58/245 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs199687324; called by muse, mutect2, varscan2
- MEGF10 | c.1402G>T p.D468Y | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs745877628; called by muse, mutect2, varscan2
- MPIG6B | c.247C>G p.R83G | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV65389269; called by muse, mutect2, varscan2
- MYH11 | c.4073C>G p.A1358G | Missense Mutation (SNP) | VAF 117/569 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.139); catalogued as COSV100258257; called by muse, mutect2, varscan2
- NCOR2 | c.3590-1G>A p.X1197_splice | Splice Site (SNP) | VAF 105/221 reads (48%) | catalogued as rs1188860390; called by muse, mutect2, varscan2
- NLRP11 | c.3086C>A p.S1029Y | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV64088694; called by muse, mutect2, varscan2
- OASL | c.715C>A p.L239I | Missense Mutation (SNP) | VAF 186/369 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1260640134; called by muse, varscan2
- ODAM | c.647T>C p.M216T | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.048); catalogued as rs1251062462; called by muse, mutect2, varscan2
- OR4K2 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100064418; called by muse, mutect2, varscan2
- OR8K1 | c.566C>A p.P189H | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.654); catalogued as COSV54404458; called by muse, mutect2, varscan2
- PCDHB3 | c.2050G>T p.D684Y | Missense Mutation (SNP) | VAF 56/268 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV50566882; called by muse, varscan2
- PRDM13 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65029042; called by muse, mutect2, varscan2
- PTPRC | c.1694C>A p.P565H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs761297445, COSV61419088; called by muse, mutect2, varscan2
- RGN | c.527A>G p.D176G | Missense Mutation (SNP) | VAF 49/75 reads (65%) | SIFT tolerated (0.16); PolyPhen benign (0.168); catalogued as COSV60275949; called by muse, mutect2, varscan2
- RSBN1 | c.961A>T p.N321Y | Missense Mutation (SNP) | VAF 76/249 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV54735531; called by muse, mutect2, varscan2
- RYR2 | c.2300C>T p.S767L | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs749979131, COSV63684329; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- S100P | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs775589745, COSV99588553; called by muse, mutect2, varscan2
- SDCCAG8 | c.547-1G>T p.X183_splice | Splice Site (SNP) | VAF 106/386 reads (27%) | catalogued as COSV100654737; called by muse, mutect2, varscan2
- SLC4A10 | c.1731G>T p.K577N (on ENST00000446997 / NM_001354461.2; = p.K547N on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs534495211, COSV55764267, COSV99764098; called by muse, mutect2, varscan2
- SRMS | c.648G>T p.K216N | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.11); catalogued as COSV99421102; called by muse, mutect2
- TTN | c.13882C>A p.L4628I (on ENST00000591111; = p.L3701I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/109 reads (28%) | PolyPhen possibly damaging (0.741); catalogued as COSV100604836, COSV60099765; called by muse, mutect2, varscan2
- TTN | c.812T>C p.I271T | Missense Mutation (SNP) | VAF 125/441 reads (28%) | PolyPhen benign (0); catalogued as rs758116718; called by muse, mutect2, varscan2
- UNKL | c.1045G>T p.A349S | Missense Mutation (SNP) | VAF 87/245 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV66768579; called by muse, mutect2, varscan2
- ZKSCAN3 | c.1195G>T p.E399* | Nonsense Mutation (SNP) | VAF 17/72 reads (24%) | catalogued as COSV52854199; called by muse, mutect2, varscan2
- ZNF692 | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 126/493 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as COSV100133679; called by muse, mutect2, varscan2
- ZSCAN5A | c.581G>T p.R194M | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.293); catalogued as COSV54223291, COSV99570408; called by muse, mutect2, varscan2
- ADPGK | c.460-2dup p.X154_splice | Splice Site (INS) | VAF 3/26 reads (12%) | called by mutect2, pindel
- ARMC4 | c.1258G>C p.E420Q | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.26); called by mutect2, varscan2
- ASAH2 | c.1396G>T p.G466C | Missense Mutation (SNP) | VAF 130/441 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- ASXL2 | c.3538G>C p.D1180H | Missense Mutation (SNP) | VAF 55/299 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- ATG4C | c.152A>T p.K51I | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- AXDND1 | c.2966A>T p.E989V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- BBX | c.2525G>T p.R842L (on ENST00000325805 / NM_001142568.3; = p.R812L on NM_020235.7) | Missense Mutation (SNP) | VAF 96/410 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- BCAS3 | c.850G>C p.G284R | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C5AR1 | c.721C>A p.L241I | Missense Mutation (SNP) | VAF 69/143 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- C6orf163 | c.50A>C p.N17T | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- CADPS2 | c.3633G>T p.M1211I | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC168 | c.13142G>T p.G4381V | Missense Mutation (SNP) | VAF 56/106 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- CDH19 | c.1667G>T p.G556V | Missense Mutation (SNP) | VAF 42/210 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- CDH19 | c.1666G>T p.G556* | Nonsense Mutation (SNP) | VAF 42/212 reads (20%) | called by muse, mutect2
- CDHR1 | c.1153A>C p.N385H | Missense Mutation (SNP) | VAF 103/326 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- CDK14 | c.859A>T p.T287S (on ENST00000380050 / NM_001287135.2; = p.T269S on NM_012395.3) | Missense Mutation (SNP) | VAF 86/265 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CDX2 | c.841C>A p.P281T | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- CELA2A | c.199T>A p.W67R | Missense Mutation (SNP) | VAF 119/382 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFAP54 | c.8693G>T p.S2898I | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.516); called by muse, varscan2
- CHAT | c.815A>C p.Q272P | Missense Mutation (SNP) | VAF 115/409 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- COL22A1 | c.1166C>A p.P389H | Missense Mutation (SNP) | VAF 92/290 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL4A4 | c.854del p.G285Dfs*40 | Frame Shift Del (DEL) | VAF 23/132 reads (17%) | called by mutect2, pindel, varscan2
- CUX2 | c.877C>G p.L293V | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT tolerated (0.69); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- CYLD | c.469_470insTA p.T157Ifs*47 | Frame Shift Ins (INS) | VAF 32/84 reads (38%) | called by mutect2, varscan2
- CYLD | c.470delinsTAG p.T157Ifs*47 | Frame Shift Ins (INS) | VAF 33/84 reads (39%) | called by mutect2*, pindel, varscan2*
- DAAM2 | c.2395C>A p.L799I | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DAPK3 | c.1208T>C p.L403P | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- ENO3 | c.310dup p.S104Ffs*17 | Frame Shift Ins (INS) | VAF 187/356 reads (53%) | called by mutect2, pindel, varscan2
- EXPH5 | c.3341del p.P1114Hfs*30 | Frame Shift Del (DEL) | VAF 37/114 reads (32%) | called by pindel, varscan2
- FAM98A | c.214G>T p.A72S | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- FAP | c.1763T>A p.V588E | Missense Mutation (SNP) | VAF 55/200 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- FCRL3 | c.1280G>T p.S427I | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- FLT3 | c.674T>G p.F225C | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); called by muse, mutect2
- GCNT4 | c.294G>C p.L98F | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- GEM | c.682G>T p.V228L | Missense Mutation (SNP) | VAF 88/259 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- IDO2 | c.21T>C p.Y7= | Splice Region (SNP) | VAF 23/57 reads (40%) | called by muse, mutect2, varscan2
- IGFL2 | c.335G>A p.C112Y (on ENST00000377693 / NM_001135113.2; = p.C123Y on NM_001002915.2) | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITGA2 | c.1817G>T p.G606V | Missense Mutation (SNP) | VAF 97/289 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- ITGB3 | c.2167C>G p.L723V | Missense Mutation (SNP) | VAF 313/503 reads (62%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- KCND2 | c.1766A>T p.E589V | Missense Mutation (SNP) | VAF 49/185 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- KCNV1 | c.521A>G p.Q174R | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- KIAA1841 | c.1532G>A p.C511Y | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LAMA2 | c.1248C>A p.C416* | Nonsense Mutation (SNP) | VAF 73/294 reads (25%) | called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.23G>C p.S8T | Missense Mutation (SNP) | VAF 142/213 reads (67%) | SIFT tolerated (0.23); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- MAD1L1 | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 38/101 reads (38%) | called by muse, mutect2, varscan2
- MYO10 | c.2692G>A p.E898K | Missense Mutation (SNP) | VAF 69/269 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- MYPN | c.2945G>A p.G982E | Missense Mutation (SNP) | VAF 112/362 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NKAIN4 | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 34/113 reads (30%) | called by muse, mutect2, varscan2
- NOS1 | c.3593C>A p.A1198D | Missense Mutation (SNP) | VAF 101/226 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOS2 | c.3321G>T p.E1107D | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT tolerated (0.53); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- NOS2 | c.3320A>T p.E1107V | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT tolerated (0.26); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- NPAP1 | c.1013T>A p.L338Q | Missense Mutation (SNP) | VAF 50/165 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- NPAT | c.2691G>C p.M897I | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- NWD2 | c.218A>C p.E73A | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.956); called by muse, mutect2
- NYAP2 | c.1813G>T p.G605* | Nonsense Mutation (SNP) | VAF 64/247 reads (26%) | called by muse, mutect2, varscan2
- OLFM3 | c.131C>A p.T44N (on ENST00000338858 / NM_001288821.1; = p.T24N on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT tolerated, low confidence (0.36); PolyPhen probably damaging (0.95); called by muse, varscan2
- OR5L1 | c.537T>A p.C179* | Nonsense Mutation (SNP) | VAF 59/148 reads (40%) | called by muse, mutect2, varscan2
- OR8K3 | c.774C>A p.Y258* | Nonsense Mutation (SNP) | VAF 52/201 reads (26%) | called by muse, mutect2, varscan2
- PAPOLB | c.283G>T p.G95* | Nonsense Mutation (SNP) | VAF 46/155 reads (30%) | called by muse, mutect2, varscan2
- PIK3AP1 | c.1783G>T p.D595Y | Missense Mutation (SNP) | VAF 67/250 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLEKHB1 | c.321C>A p.H107Q | Missense Mutation (SNP) | VAF 77/255 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- PNMA2 | c.431A>T p.H144L | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- POTEJ | c.1621C>A p.P541T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by mutect2, varscan2
- PRAMEF20 | c.930G>C p.L310F | Missense Mutation (SNP) | VAF 170/622 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRDM15 | c.3109G>T p.E1037* | Nonsense Mutation (SNP) | VAF 20/320 reads (6%) | called by muse, mutect2
- PTPRN2 | c.831G>C p.R277S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.245); called by muse, mutect2
- PUS1 | c.132G>T p.Q44H | Missense Mutation (SNP) | VAF 109/386 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- RANGRF | c.105A>T p.Q35H | Missense Mutation (SNP) | VAF 151/308 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- RGSL1 | c.1447T>A p.Y483N | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- RIOX2 | c.620G>C p.R207P | Missense Mutation (SNP) | VAF 35/276 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- RTN4 | c.914G>C p.S305T | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SBF1 | c.655+2T>C p.X219_splice | Splice Site (SNP) | VAF 32/81 reads (40%) | called by muse, mutect2, varscan2
- SBK3 | c.765C>A p.F255L | Missense Mutation (SNP) | VAF 54/96 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SCARA5 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEMA5B | c.1023G>T p.K341N | Missense Mutation (SNP) | VAF 118/524 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC17A7 | c.1457A>T p.Y486F | Missense Mutation (SNP) | VAF 71/116 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- SLC44A5 | c.2007C>G p.S669R | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- SLC4A10 | c.2467C>G p.L823V (on ENST00000446997 / NM_001354461.2; = p.L793V on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SLC6A15 | c.1345del p.A449Rfs*2 | Frame Shift Del (DEL) | VAF 42/129 reads (33%) | called by mutect2, pindel, varscan2
- SLC7A3 | c.858G>T p.M286I | Missense Mutation (SNP) | VAF 102/151 reads (68%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SMCHD1 | c.360C>G p.H120Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SMYD1 | c.1342C>A p.L448I | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SMYD4 | c.2378T>A p.L793* | Nonsense Mutation (SNP) | VAF 178/259 reads (69%) | called by muse, mutect2, varscan2
- SNAP91 | c.2526+2T>A p.X842_splice | Splice Site (SNP) | VAF 49/168 reads (29%) | called by muse, mutect2, varscan2
- SNX9 | c.308G>A p.S103N | Missense Mutation (SNP) | VAF 64/208 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPTBN5 | c.6191T>A p.I2064N | Missense Mutation (SNP) | VAF 6/129 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, mutect2
- SUZ12 | c.1083_1104del p.W361Cfs*39 | Frame Shift Del (DEL) | VAF 43/104 reads (41%) | called by mutect2, pindel, varscan2
- SYNE1 | c.1299G>T p.Q433H (on ENST00000367255 / NM_182961.4; = p.Q440H on NM_033071.3) | Missense Mutation (SNP) | VAF 114/404 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- TANC2 | c.1978A>C p.T660P | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- TBC1D12 | c.1601-4G>T | Splice Region (SNP) | VAF 17/80 reads (21%) | called by muse, mutect2, varscan2
- TBRG4 | c.917G>T p.S306I | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- TET2 | c.483A>T p.K161N | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TGIF2LX | c.696del p.E232Dfs*2 | Frame Shift Del (DEL) | VAF 45/86 reads (52%) | called by mutect2, pindel, varscan2
- TLN2 | c.2110A>T p.R704W | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- TMC3 | c.315C>A p.L105= | Splice Region (SNP) | VAF 49/167 reads (29%) | called by muse, mutect2, varscan2
- TMEM132C | c.1346C>A p.T449K | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TMEM192 | c.311G>C p.W104S | Missense Mutation (SNP) | VAF 63/184 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM39A | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 56/251 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNFRSF1B | c.1076G>T p.G359V | Missense Mutation (SNP) | VAF 93/270 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- TNR | c.718A>T p.S240C | Missense Mutation (SNP) | VAF 64/203 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- TRIM3 | c.1262C>G p.P421R | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.05); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- TRIM51GP | c.905T>C p.L302P | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- TRPA1 | c.1898G>T p.C633F | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, varscan2
- TRPC3 | c.427G>C p.V143L (on ENST00000379645 / NM_001366479.2; = p.V70L on NM_003305.2) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TTC21B | c.1087G>T p.G363* | Nonsense Mutation (SNP) | VAF 21/120 reads (18%) | called by muse, varscan2
- TULP4 | c.3356C>T p.P1119L | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TYRO3 | c.767A>T p.Q256L | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UNCX | c.865del p.Q289Kfs*84 | Frame Shift Del (DEL) | VAF 65/201 reads (32%) | called by mutect2, pindel*, varscan2
- VWA5B1 | c.569A>G p.D190G | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- WDR49 | c.1625A>G p.K542R (on ENST00000308378 / NM_001366158.1; = p.K883R on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- WNK3 | c.2104T>A p.L702M | Missense Mutation (SNP) | VAF 48/80 reads (60%) | SIFT tolerated (0.2); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- XRRA1 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- ZNF572 | c.593G>T p.S198I | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- ZNF644 | c.3274del p.I1092Sfs*2 | Frame Shift Del (DEL) | VAF 17/72 reads (24%) | called by mutect2, pindel, varscan2
- ZNFX1 | c.3960_3975del p.P1321Sfs*21 | Frame Shift Del (DEL) | VAF 90/343 reads (26%) | called by mutect2, pindel, varscan2
- ABHD17B | c.372A>T p.S124= | Silent (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
- AC100868.1 | c.1914A>G p.E638= | Silent (SNP) | VAF 50/175 reads (29%) | catalogued as rs368698444; called by muse, mutect2, varscan2
- ANK2 | c.162C>A p.G54= | Silent (SNP) | VAF 75/265 reads (28%) | catalogued as COSV100004912; called by muse, mutect2, varscan2
- BHLHE22 | c.249C>A p.G83= | Silent (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- BMPR1B | c.87C>G p.V29= | Silent (SNP) | VAF 66/236 reads (28%) | called by muse, mutect2, varscan2
- CECR2 | c.2346G>C p.S782= (on ENST00000342247 / NM_001290047.2; = p.S599= on NM_001290046.1) | Silent (SNP) | VAF 101/359 reads (28%) | catalogued as COSV52841678, COSV99378996; called by muse, mutect2, varscan2
- CHADL | c.1926G>T p.G642= | Silent (SNP) | VAF 55/158 reads (35%) | called by muse, mutect2, varscan2
- COBLL1 | c.2877A>T p.A959= (on ENST00000392717; = p.A921= on NM_014900.5) | Silent (SNP) | VAF 51/144 reads (35%) | called by muse, mutect2, varscan2
- COLEC12 | c.1023G>A p.T341= | Silent (SNP) | VAF 76/218 reads (35%) | catalogued as rs750057361, COSV68369922; called by muse, mutect2, varscan2
- DMBX1 | c.765C>G p.S255= | Silent (SNP) | VAF 52/166 reads (31%) | called by muse, mutect2
- ESPL1 | c.3408A>T p.I1136= | Silent (SNP) | VAF 58/171 reads (34%) | called by muse, mutect2, varscan2
- FMR1NB | c.135C>T p.Y45= | Silent (SNP) | VAF 99/162 reads (61%) | catalogued as rs782543016, COSV65072996; called by muse, mutect2, varscan2
- FSHR | c.1077C>T p.I359= | Silent (SNP) | VAF 21/402 reads (5%) | catalogued as COSV100437360, COSV58624392; called by muse, mutect2
- GALNT17 | c.282G>T p.R94= | Silent (SNP) | VAF 42/110 reads (38%) | catalogued as COSV61145715; called by muse, mutect2, varscan2
- GFOD1 | c.849G>T p.T283= | Silent (SNP) | VAF 65/186 reads (35%) | called by muse, mutect2, varscan2
- GRIN2B | c.129C>A p.G43= | Silent (SNP) | VAF 84/260 reads (32%) | called by muse, mutect2, varscan2
- HELB | c.3126T>C p.G1042= | Silent (SNP) | VAF 33/97 reads (34%) | called by muse, mutect2, varscan2
- HERC2 | c.673T>C p.L225= | Silent (SNP) | VAF 34/138 reads (25%) | catalogued as COSV99878049; called by muse, mutect2, varscan2
- IGSF9B | c.2577G>T p.V859= | Silent (SNP) | VAF 40/128 reads (31%) | called by muse, mutect2, varscan2
- IL2RG | c.888A>G p.L296= | Silent (SNP) | VAF 158/233 reads (68%) | catalogued as rs1409653685; called by muse, mutect2, varscan2
- KAZN | c.15T>C p.N5= | Silent (SNP) | VAF 144/472 reads (31%) | catalogued as rs780249420; called by muse, mutect2, varscan2
- LHFPL4 | c.216C>A p.G72= | Silent (SNP) | VAF 13/108 reads (12%) | called by muse, mutect2, varscan2
- MYO1A | c.1407A>C p.L469= | Silent (SNP) | VAF 203/623 reads (33%) | called by muse, mutect2, varscan2
- NCOA3 | c.2025G>T p.G675= | Silent (SNP) | VAF 31/251 reads (12%) | called by muse, mutect2, varscan2
- NYAP2 | c.1812G>T p.A604= | Silent (SNP) | VAF 65/251 reads (26%) | catalogued as rs989073141; called by muse, mutect2, varscan2
- PIK3CB | c.3210T>C p.S1070= | Silent (SNP) | VAF 51/266 reads (19%) | called by muse, mutect2, varscan2
- PRDM9 | c.1747A>C p.R583= | Silent (SNP) | VAF 95/520 reads (18%) | called by muse, mutect2, varscan2
- ROBO2 | c.364C>A p.R122= | Silent (SNP) | VAF 79/150 reads (53%) | catalogued as COSV59895891; called by muse, mutect2, varscan2
- RYR3 | c.10677T>C p.F3559= (on ENST00000389232; = p.F3560= on NM_001036.6) | Silent (SNP) | VAF 31/155 reads (20%) | called by muse, mutect2, varscan2
- SIX4 | c.507C>T p.L169= | Silent (SNP) | VAF 72/150 reads (48%) | called by muse, mutect2, varscan2
- SLC35F4 | c.474G>A p.T158= (on ENST00000339762 / NM_001352015.2; = p.T122= on NM_001206920.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/96 reads (41%) | catalogued as rs1466973964; called by muse, mutect2, varscan2
- SLC3A1 | c.1866A>G p.L622= | Silent (SNP) | VAF 127/271 reads (47%) | called by muse, mutect2, varscan2
- SLC7A10 | c.361C>T p.L121= | Silent (SNP) | VAF 303/1232 reads (25%) | called by muse, mutect2, varscan2
- SPEG | c.4623C>A p.S1541= | Silent (SNP) | VAF 49/164 reads (30%) | called by muse, mutect2, varscan2
- SSH1 | c.246C>A p.I82= | Silent (SNP) | VAF 68/386 reads (18%) | called by muse, varscan2
- TDRD15 | c.3412T>C p.L1138= | Silent (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- TMEM252 | c.387G>A p.T129= | Silent (SNP) | VAF 42/74 reads (57%) | catalogued as rs200605675; called by muse, mutect2, varscan2
- TRIM9 | c.1794G>T p.V598= | Silent (SNP) | VAF 169/378 reads (45%) | called by muse, mutect2, varscan2
- UNC93B1 | c.1650C>T p.S550= | Silent (SNP) | VAF 16/353 reads (5%) | called by muse, mutect2
- UNKL | c.1044G>T p.P348= | Silent (SNP) | VAF 86/245 reads (35%) | called by muse, mutect2, varscan2
- ZFHX4 | c.3009C>A p.A1003= | Silent (SNP) | VAF 76/232 reads (33%) | called by muse, varscan2
- AC025575.2 | n.85T>C | RNA (SNP) | VAF 34/181 reads (19%) | called by muse, mutect2, varscan2
- AC136759.1 | n.1247G>A | RNA (SNP) | VAF 124/463 reads (27%) | catalogued as rs754776014; called by muse, mutect2, varscan2
- AL136982.4 | n.788G>T | RNA (SNP) | VAF 179/595 reads (30%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73825947 A>G | 5'Flank (SNP) | VAF 81/132 reads (61%) | called by muse, mutect2, varscan2
- AQP1 | c.385-371A>G | Intron (SNP) | VAF 79/313 reads (25%) | catalogued as rs1272693562; called by muse, mutect2, varscan2
- ARL13B | c.*80G>T | 3'UTR (SNP) | VAF 43/288 reads (15%) | called by muse, mutect2, varscan2
- CABIN1 | c.3786+20G>T | Intron (SNP) | VAF 44/115 reads (38%) | called by muse, mutect2, varscan2
- CCDC144A | c.3372+1915A>T | Intron (SNP) | VAF 20/32 reads (63%) | called by mutect2, varscan2
- CSMD3 | c.9863-21C>A | Intron (SNP) | VAF 30/108 reads (28%) | called by muse, mutect2, varscan2
- DEF8 | c.1186-67G>T | Intron (SNP) | VAF 37/74 reads (50%) | called by muse, mutect2, varscan2
- EP400P1 | n.442G>T | RNA (SNP) | VAF 123/259 reads (47%) | called by muse, mutect2, varscan2
- EYS | c.1767-7529G>T | Intron (SNP) | VAF 8/27 reads (30%) | catalogued as COSV65459418; called by mutect2, varscan2
- GNAS | c.*262A>C | 3'UTR (SNP) | VAF 31/89 reads (35%) | called by muse, mutect2, varscan2
- HSP90AA4P | n.1710A>G | RNA (SNP) | VAF 25/92 reads (27%) | catalogued as rs1473750179; called by muse, mutect2, varscan2
- LINC00840 | n.394C>A | RNA (SNP) | VAF 49/192 reads (26%) | called by muse, mutect2, varscan2
- MGLL | c.481-5142G>T | Intron (SNP) | VAF 227/422 reads (54%) | called by muse, mutect2, varscan2
- MPP4 | c.-137C>A | 5'UTR (SNP) | VAF 13/74 reads (18%) | called by muse, mutect2, varscan2
- NSMCE4A | c.845-523C>A | Intron (SNP) | VAF 14/62 reads (23%) | called by muse, mutect2, varscan2
- PARD6G | c.295+19575G>C | Intron (SNP) | VAF 56/192 reads (29%) | called by muse, mutect2, varscan2
- PKD1 | c.7210-28G>A | Intron (SNP) | VAF 85/339 reads (25%) | catalogued as rs748713546; called by muse, mutect2, varscan2
- RNU6-713P | chr12:40557166 G>T | 5'Flank (SNP) | VAF 24/79 reads (30%) | catalogued as rs191471932; called by muse, mutect2, varscan2
- RPSA | c.-34+160G>C | Intron (SNP) | VAF 31/87 reads (36%) | called by muse, mutect2, varscan2
- SNCA | c.306+67G>T | Intron (SNP) | VAF 15/194 reads (8%) | called by muse, mutect2
- SYNE1 | c.24976+48G>T | Intron (SNP) | VAF 67/168 reads (40%) | called by muse, mutect2, varscan2
- ZNF738 | c.*1167C>T | 3'UTR (SNP) | VAF 18/53 reads (34%) | called by muse, mutect2, varscan2
